Somatic mutation profile of tumor specimen MBCProject_0771_T1_WES (aliquot MBCProject_0771_T1_WES_1) from CMI case MBCProject_0771, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 51.5 years (18,802 days).
Specimen MBCProject_0771_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43dd14a9-505b-49a1-9054-c43c542e039f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0771_SALIVA (Saliva), aliquot MBCProject_0771_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a7121ac-1324-4203-b3e5-700016ed5f23

The open-access MAF lists 198 somatic variants for this specimen: 126 protein-altering or splice-affecting, 46 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 46, Intron 12, Nonsense Mutation 8, 5'UTR 4, Splice Region 4, 5'Flank 3, 3'Flank 3, 3'UTR 3, Splice Site 2, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PROK2 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs121434272, CM065397; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs112882610, COSV63971584, COSV63972780; ClinVar: uncertain significance; called by muse, varscan2
- ANO3 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs1393695079, COSV56784081; called by muse, mutect2, varscan2
- CAMTA2 | c.3261+3G>A | Splice Region (SNP) | VAF 9/91 reads (10%) | catalogued as COSV99236715; called by muse, mutect2
- CDH1 | c.1205A>T p.D402V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55729660; called by muse, mutect2, varscan2
- CDH10 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.511); catalogued as COSV52570748; called by muse, mutect2, varscan2
- CSMD1 | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1158776972; called by mutect2, varscan2
- DNMT1 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs963570572, COSV61579881; called by muse, mutect2, varscan2
- DYNC1H1 | c.10970G>T p.G3657V | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761427653, COSV64135848; called by muse, mutect2, varscan2
- EGFLAM | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.115); catalogued as rs1222245486; called by muse, mutect2, varscan2
- ELOA | c.2236G>C p.E746Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV69311528; called by muse, mutect2, varscan2
- FANCA | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs776682683, COSV66882870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- G6PC | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs774448424, COSV53830463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCC2 | c.3977G>A p.R1326Q | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1431185464; called by muse, mutect2, varscan2
- GRIA1 | c.2596G>A p.G866R | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.196); catalogued as COSV53615081; called by muse, varscan2
- GRIP1 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 38/1436 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99670787; called by muse, mutect2
- HPS1 | c.937+3G>A | Splice Region (SNP) | VAF 25/162 reads (15%) | catalogued as COSV57267266; called by muse, mutect2, varscan2
- IGF2BP3 | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as COSV51683015; called by muse, mutect2, varscan2
- KIRREL3 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs200090559; called by muse, mutect2, varscan2
- KMT5A | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100389471, COSV57862650; called by mutect2, varscan2
- KRT10 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV99510042; called by muse, mutect2, varscan2
- LDHAL6B | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.04); catalogued as COSV55695217; called by muse, mutect2, varscan2
- NOD1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs570225517, COSV56111447; called by mutect2, varscan2
- OR5B12 | c.744C>G p.I248M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV56904688, COSV56905479; called by muse, varscan2
- PAGE1 | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as COSV101093913; called by muse, mutect2, varscan2
- POTEM | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1422795627, COSV69154507; called by muse, mutect2, varscan2
- PSME4 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV66364404; called by muse, mutect2, varscan2
- PTCD1 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.917); catalogued as rs777645699; called by muse, mutect2, varscan2
- RMI1 | c.1442C>G p.S481C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV57938421; called by muse, mutect2, varscan2
- RNF111 | c.1813C>G p.Q605E | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs1055168382, COSV62085730; called by muse, mutect2, varscan2
- SLC13A2 | c.1187-1G>A p.X396_splice | Splice Site (SNP) | VAF 29/209 reads (14%) | catalogued as COSV100120152; called by muse, mutect2, varscan2
- SLC16A3 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568541564; called by muse, mutect2
- SLC45A1 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as rs749157979, COSV57096638; called by muse, mutect2, varscan2
- SLC4A4 | c.1114G>A p.E372K (on ENST00000264485 / NM_001098484.3; = p.E328K on NM_003759.4) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99140399; called by muse, mutect2, varscan2
- SUPT20H | c.2156G>A p.R719K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.931); catalogued as COSV53508867; called by mutect2, varscan2
- SYNE2 | c.15385G>A p.D5129N | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs931728993; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCAP | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV54094197; called by muse, mutect2, varscan2
- TEX14 | c.1155C>G p.I385M (on ENST00000240361 / NM_001201457.2; = p.I379M on NM_031272.5) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV53611543; called by muse, mutect2, varscan2
- THBS1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.096); catalogued as rs1236362449, COSV52953588, COSV52955289; called by muse, mutect2
- TTN | c.35338C>T p.P11780S (on ENST00000591111; = p.P10853S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | PolyPhen possibly damaging (0.447); catalogued as COSV60291049; called by mutect2, varscan2
- TYR | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1288816930; called by muse, mutect2, varscan2
- UQCRC1 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99179008; called by muse, mutect2
- VAMP5 | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV60498422, COSV60499154; called by muse, varscan2
- ZFHX4 | c.8401G>C p.D2801H | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs1324606568; called by muse, mutect2
- ZNF440 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.026); catalogued as COSV58370319; called by muse, mutect2
- ZNF503 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1180056358; called by muse, mutect2
- ZNF664 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61877217; called by muse, mutect2, varscan2
- ADGRA2 | c.3793G>C p.E1265Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ADK | c.907G>A p.D303N (on ENST00000286621; = p.D286N on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- AIG1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ALG10B | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- APOO | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- ARFGEF3 | c.2359G>C p.E787Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARHGEF17 | c.5929G>A p.A1977T | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ART1 | c.920C>G p.S307C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- B3GNT6 | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- BIRC6 | c.9694C>G p.L3232V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by mutect2, varscan2
- BTBD9 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC150 | c.2446G>C p.E816Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCNJL | c.863G>A p.S288N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CEMP1 | c.530C>G p.S177* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2, varscan2
- CENPS | c.210-1G>C p.X70_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- CHP2 | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DACT2 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.163); called by muse, mutect2
- DPH1 | c.*16C>T | Splice Region (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- DSC3 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, varscan2
- DYNC2H1 | c.6778C>G p.L2260V | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- EDC3 | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMILIN1 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.046); called by muse, mutect2
- FAM111A | c.35C>G p.S12* | Nonsense Mutation (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- FAM160B2 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.034); called by muse, mutect2
- FAM184B | c.1681G>C p.D561H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- FBXO30 | c.2076G>C p.W692C | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAB1 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- GMCL2 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); called by mutect2, varscan2
- GPKOW | c.1355G>A p.R452K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRHL3 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- HERC6 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- HMCN1 | c.9793G>C p.E3265Q | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); called by muse, mutect2
- HSPA1L | c.902G>C p.R301T | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HUWE1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- IGSF10 | c.3847C>A p.L1283I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, varscan2
- ITCH | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITCH | c.1105G>A p.D369N (on ENST00000262650 / NM_001257137.3; = p.D328N on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- KALRN | c.5761G>A p.E1921K (on ENST00000360013 / NM_001024660.4; = p.E224K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- KCNMA1 | c.3223C>G p.L1075V (on ENST00000286628 / NM_001161352.2; = p.L1017V on NM_002247.4) | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.186); called by muse, mutect2
- KIF1B | c.4973C>G p.S1658C (on ENST00000377086 / NM_001365952.1; = p.S1612C on NM_015074.3) | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.443); called by muse, mutect2
- MAP3K21 | c.2572G>A p.D858N | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MICU2 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIER1 | c.964G>A p.E322K (on ENST00000355356 / NM_001077701.3; = p.E339K on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- MRPS27 | c.396G>A p.K132= | Splice Region (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- MUCL3 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- NSD3 | c.3554G>C p.R1185T | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2
- OR6N2 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PCNP | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIGH | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PLCG1 | c.3571C>T p.P1191S | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- POLN | c.843C>G p.I281M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- POTEF | c.2017G>C p.E673Q | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRIMPOL | c.611A>G p.D204G | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRKCA | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, mutect2
- PTPRD | c.3166G>A p.D1056N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.005); called by muse, mutect2
- RNF5 | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0.109); called by muse, mutect2
- SERINC2 | c.1025C>T p.S342L (on ENST00000373709 / NM_178865.5; = p.S346L on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC34A3 | c.978C>G p.I326M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SLC35B3 | c.1175G>C p.R392T | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.101); called by muse, mutect2
- SLC44A4 | c.2132G>C p.*711Sext*5 | Nonstop Mutation (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2
- SLC44A4 | c.1353C>A p.F451L | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SMARCA5 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- STAG1 | c.2400G>A p.M800I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TANC2 | c.1436T>G p.L479R | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TBX3 | c.731C>G p.S244C (on ENST00000257566 / NM_016569.4; = p.S224C on NM_005996.4) | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TJP1 | c.1879C>T p.Q627* | Nonsense Mutation (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2
- TMPRSS11B | c.441T>A p.N147K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.071); called by muse, varscan2
- UBR1 | c.2718G>C p.W906C | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UGT2B11 | c.793C>G p.Q265E | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP41 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- WDR87 | c.2875C>G p.L959V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- WIZ | c.2786C>G p.S929C (on ENST00000673675 / NM_001371589.1; = p.S106C on NM_001330395.4) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- WNT8A | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- YTHDC2 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- ZCCHC7 | c.1557G>T p.K519N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ZNF540 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF595 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF735 | c.1050G>C p.E350D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ABCC8 | c.1248G>A p.Q416= | Silent (SNP) | VAF 14/112 reads (13%) | called by mutect2, varscan2
- AP3D1 | c.684G>A p.L228= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- B3GNT6 | c.90C>T p.F30= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- BIK | c.453C>T p.L151= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs750496593; called by muse, mutect2, varscan2
- BPIFB1 | c.606C>T p.P202= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs372508992; called by mutect2, varscan2
- CHL1 | c.48C>T p.F16= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- CORO2A | c.447C>T p.F149= | Silent (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- CPNE6 | c.330G>A p.T110= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs746836389, COSV53744438; called by mutect2, varscan2
- CPSF4 | c.15C>T p.I5= | Silent (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- CPSF6 | c.427C>T p.L143= | Silent (SNP) | VAF 34/406 reads (8%) | called by muse, mutect2
- CROCC2 | c.4422G>A p.T1474= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs545887290; called by muse, mutect2
- DNMBP | c.4686G>A p.K1562= | Silent (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- DPP9 | c.1698G>C p.V566= (on ENST00000598800; = p.V595= on NM_139159.5) | Silent (SNP) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- EID2 | c.285G>A p.P95= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs1181604994; called by muse, mutect2, varscan2
- ENTPD1 | c.996C>T p.L332= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as rs1001938811; called by muse, mutect2
- FAT3 | c.11829G>A p.A3943= | Silent (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- FBXL6 | c.888C>T p.C296= | Silent (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- FBXL8 | c.1050C>T p.H350= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs763634014; called by muse, mutect2, varscan2
- ITSN2 | c.4536C>T p.V1512= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- KAT5 | c.447G>A p.R149= | Silent (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1122C>T p.L374= | Silent (SNP) | VAF 17/176 reads (10%) | catalogued as rs781404437; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP1B | c.4788C>T p.F1596= | Silent (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- MAST2 | c.1362T>C p.I454= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as rs1349981444; called by muse, mutect2, varscan2
- MEI1 | c.9G>C p.V3= | Silent (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- MUC5B | c.9492C>T p.L3164= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs1274883098, COSV71593933; called by muse, mutect2
- NEURL1 | c.1029G>A p.T343= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- NUP160 | c.1626C>G p.L542= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- NYX | c.117C>T p.T39= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs1028104555, COSV100699497; called by muse, mutect2, varscan2
- ORC2 | c.1224C>T p.I408= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- OTUB1 | c.288C>T p.F96= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs548762142, COSV55360577; called by muse, mutect2, varscan2
- PARP1 | c.2376C>G p.V792= | Silent (SNP) | VAF 17/176 reads (10%) | called by muse, mutect2, varscan2
- PDCD11 | c.144G>A p.Q48= | Silent (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- POGZ | c.963G>C p.V321= | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as rs1211508674; called by muse, varscan2
- RFX3 | c.2142T>G p.T714= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- RHOT1 | c.612C>G p.L204= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs1247156519; called by muse, mutect2
- RHOT1 | c.699C>G p.V233= | Silent (SNP) | VAF 9/118 reads (8%) | called by muse, mutect2
- SDHAF2 | c.324G>C p.L108= | Silent (SNP) | VAF 26/193 reads (13%) | called by muse, mutect2, varscan2
- SRMS | c.243C>T p.L81= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs565672810; called by muse, mutect2, varscan2
- TNXB | c.1425C>A p.R475= | Silent (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- TRPS1 | c.1866C>T p.T622= (on ENST00000220888 / NM_001330599.2; = p.T635= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99631021; called by muse, mutect2, varscan2
- UBALD1 | c.42C>T p.I14= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV52082599; called by muse, mutect2, varscan2
- USP41 | c.528G>A p.L176= | Silent (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- WASHC2C | c.798G>A p.E266= | Silent (SNP) | VAF 18/135 reads (13%) | called by muse, mutect2, varscan2
- Z83844.2 | c.211C>T p.L71= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- ZNF544 | c.411G>A p.E137= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV54135921; called by muse, varscan2
- ZNF571 | c.1645C>T p.L549= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- ACSF2 | c.129-419C>G | Intron (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- ALG2 | c.*250C>T | 3'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- APOOP5 | chr16:59751995 C>T | 3'Flank (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2
- ENAM | c.535-22C>T | Intron (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- FABP5P3 | chr7:152446294 G>A | 3'Flank (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- FAM240C | c.12+1231C>T | Intron (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2
- GYPA | c.271+21G>C | Intron (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- ITGA2 | c.-49C>T | 5'UTR (SNP) | VAF 47/133 reads (35%) | catalogued as rs1281256406; called by muse, mutect2, varscan2
- KIF12 | c.26+25G>C | Intron (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- LBP | c.*209G>A | 3'UTR (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-5324G>C | Intron (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- NGRN | chr15:90275418 del T | 3'Flank (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- ODF2 | c.-242C>T | 5'UTR (SNP) | VAF 35/103 reads (34%) | called by muse, mutect2, varscan2
- PABPC1L | c.1660+221C>T | Intron (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- PCBP3 | c.*23G>A | 3'UTR (SNP) | VAF 4/17 reads (24%) | catalogued as rs201400266, COSV68406989; called by mutect2, varscan2
- PTGER3 | c.*24-16391C>G | Intron (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- RANBP17 | chr5:170861984 C>T | 5'Flank (SNP) | VAF 5/34 reads (15%) | catalogued as rs1423687321; called by muse, mutect2, varscan2
- RHBDD1 | c.857-7053G>C | Intron (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- RNF44 | c.1236+73C>T | Intron (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- RPS26P15 | n.275G>A | RNA (SNP) | VAF 22/62 reads (35%) | catalogued as rs768731084; called by muse, mutect2, varscan2
- SPI1 | c.-22G>A | 5'UTR (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- TMEM147 | chr19:35545378 C>T | 5'Flank (SNP) | VAF 41/141 reads (29%) | called by muse, mutect2, varscan2
- TSN | c.67-660C>G | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as rs1202689476, COSV67606000; called by muse, mutect2, varscan2
- TTC19 | c.995-31C>A | Intron (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- UNC13B | c.-55G>C | 5'UTR (SNP) | VAF 13/188 reads (7%) | called by muse, mutect2
- ZSWIM8 | chr10:73785613 T>C | 5'Flank (SNP) | VAF 52/176 reads (30%) | called by muse, mutect2, varscan2
